Gene-level copy-number profile of tumor specimen TCGA-ZF-AA4N-01A from TCGA case TCGA-ZF-AA4N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,056 days).
Specimen TCGA-ZF-AA4N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2aa6a001-3ee8-4c3d-8a05-23a8fdd0b6b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA4N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4aa685c1-b6cd-441d-92e5-3b17f5de506d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,874; copy number 3: 5,343; copy number 4: 38,139; copy number 5: 7,669; copy number 6: 3,166; copy number 7: 1,191; copy number 8: 108; copy number 9: 43; copy number 10: 100; copy number 11: 283; copy number 12: 828; copy number 13: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA4N-01A-11D-A38F-01): tumor purity 0.77, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,325 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 11–12 (broad region; genes not listed).
- chr7:94,782,886–101,224,190, 209 genes, copy number 9–12 (within-gene range 5–12) (broad region; genes not listed).
- chr7:130,380,339–134,679,816, 71 genes, copy number 13 (within-gene range 5–13) (broad region; genes not listed).
- chr7:138,797,952–148,963,410, 299 genes, copy number 9–12 (within-gene range 5–12) (broad region; genes not listed).
- chr9:4,792,944–4,885,917, 1 gene, copy number 11 (within-gene range 4–11): RCL1.
- chr9:4,850,297–5,856,426, 34 genes, copy number 11: MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4.
- chr9:5,890,889–5,910,606, 1 gene, copy number 11: MLANA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
